Somatic mutation profile of tumor specimen TCGA-DX-A8BM-01A (aliquot TCGA-DX-A8BM-01A-11D-A417-09) from TCGA case TCGA-DX-A8BM, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 60.6 years (22,152 days).
Specimen TCGA-DX-A8BM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b64ef125-bda0-4a3d-b55e-0c043a5f7400.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BM-10B (Blood Derived Normal), aliquot TCGA-DX-A8BM-10B-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16c9aa99-2669-440a-9104-8cf2ee091ca6

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 2, Splice Region 2, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMDEC1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.245); catalogued as COSV56477081; called by muse, mutect2, varscan2
- AIPL1 | c.671A>T p.K224M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100006057; called by muse, mutect2, varscan2
- ALOX5 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 82/105 reads (78%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.839); catalogued as rs994081039, COSV65552550; called by muse, mutect2, varscan2
- ANXA4 | c.626A>T p.H209L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV101268802; called by muse, mutect2, varscan2
- APPBP2 | c.1373T>A p.I458N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99319676; called by muse, mutect2, varscan2
- ARF3 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99873131; called by muse, mutect2
- ATP7B | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as COSV54442836, COSV99666450; called by muse, mutect2, varscan2
- CAPZA3 | c.267A>T p.K89N | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV99856370; called by muse, mutect2, varscan2
- CCDC93 | c.1815C>A p.Y605* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100098800; called by muse, mutect2
- CDHR1 | c.2431G>A p.V811M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs764500651, COSV60560815; called by muse, mutect2, varscan2
- CDHR2 | c.939G>C p.E313D | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV99991625; called by muse, mutect2, varscan2
- CLIP2 | c.2904T>A p.D968E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99791583; called by muse, mutect2, varscan2
- CLIP2 | c.2905C>T p.Q969* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99791586; called by muse, mutect2, varscan2
- CNTN2 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as rs754696472, COSV100084972, COSV100085008; called by mutect2, varscan2
- CTNNA2 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV63570435; called by muse, varscan2
- CTNND2 | c.3614G>A p.R1205H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748902238, COSV58886584; called by muse, mutect2, varscan2
- DGKK | c.3611A>G p.E1204G | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV101053001; called by muse, mutect2, varscan2
- DNAH8 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV100545369; called by muse, mutect2, varscan2
- FAM171A1 | c.2657C>A p.A886E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100968270, COSV65319393; called by muse, mutect2
- FCGR3A | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100914660; called by muse, mutect2, varscan2
- GABRA1 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50100569, COSV99196184; called by muse, mutect2, varscan2
- HUWE1 | c.2626T>C p.C876R | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.177); catalogued as COSV99472399; called by muse, mutect2, varscan2
- IGF2BP1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); catalogued as rs746549698, COSV51729241; called by muse, mutect2, varscan2
- INVS | c.3105G>T p.Q1035H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV99317552; called by muse, mutect2
- KIF19 | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as COSV100739069; called by muse, mutect2, varscan2
- MDN1 | c.4537A>G p.K1513E | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as rs1481456880, COSV101021351; called by muse, mutect2, varscan2
- MYT1L | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV101220780; called by muse, mutect2, varscan2
- OR1A1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs756834855, COSV100410768; called by muse, mutect2, varscan2
- PLAGL2 | c.1313T>A p.V438D | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.686); catalogued as COSV99867257; called by muse, mutect2, varscan2
- PNPLA7 | c.1679A>G p.Y560C | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99480704; called by muse, mutect2, varscan2
- RB1 | c.1134del p.M379* | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | catalogued as CD058081; called by mutect2, pindel, varscan2
- RBM17 | c.561G>A p.E187= | Splice Region (SNP) | VAF 34/47 reads (72%) | catalogued as COSV101159105; called by muse, mutect2, varscan2
- RHOBTB1 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100558478; called by muse, mutect2
- RYR1 | c.5009G>A p.R1670H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); catalogued as rs1248039154, COSV62107618; ClinVar: uncertain significance; called by muse, mutect2
- SEZ6L | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV99962084; called by muse, mutect2, varscan2
- SPTB | c.6511G>A p.A2171T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100731126; called by muse, mutect2, varscan2
- TFR2 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs763388776, COSV56155401; called by muse, mutect2, varscan2
- TIGD7 | c.1601A>G p.N534S | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.021); catalogued as COSV99239872; called by muse, mutect2, varscan2
- TTN | c.48980G>A p.R16327H (on ENST00000591111; = p.R8903H on NM_003319.4) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | PolyPhen possibly damaging (0.804); catalogued as rs200100660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.5273A>T p.N1758I | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100234841, COSV56342971, COSV56374871; called by muse, mutect2, varscan2
- USP10 | c.1950G>C p.L650F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs1292233506, COSV99551407; called by muse, mutect2, varscan2
- USP25 | c.858G>T p.T286= | Splice Region (SNP) | VAF 21/100 reads (21%) | catalogued as COSV99583800; called by muse, mutect2, varscan2
- VPS13A | c.3022A>C p.N1008H | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100652811; called by muse, mutect2, varscan2
- WIZ | c.2491G>A p.G831S (on ENST00000673675 / NM_001371589.1; = p.G94S on NM_021241.3) | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs773347628, COSV99653215; called by muse, mutect2, varscan2
- ZNF280A | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV57482465; called by muse, mutect2, varscan2
- ZSCAN31 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100716842; called by muse, mutect2, varscan2
- ATRX | c.2381dup p.K796Qfs*4 | Frame Shift Ins (INS) | VAF 35/57 reads (61%) | called by mutect2, pindel, varscan2
- CCDC18 | c.1335-22_1338del p.X445_splice | Splice Site (DEL) | VAF 22/109 reads (20%) | called by mutect2, pindel
- PRAMEF18 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 145/496 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ATP6V0A4 | c.1420T>C p.L474= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs1414297954, COSV100023122; called by muse, mutect2, varscan2
- ELMOD1 | c.960G>A p.A320= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs764635964, COSV56192809; called by muse, mutect2, varscan2
- HAO1 | c.534G>A p.P178= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs750852016, COSV66492678; called by muse, mutect2, varscan2
- KLK12 | c.6G>A p.G2= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs552324076, COSV99141945; called by muse, mutect2, varscan2
- LRP1 | c.9687G>A p.Q3229= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99675862; called by muse, mutect2
- MUC5B | c.16650G>T p.G5550= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV101500349; called by muse, mutect2, varscan2
- PKP2 | c.1707C>T p.G569= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs780049494, COSV99297667; ClinVar: likely benign; called by muse, mutect2, varscan2
- PSMD7 | c.558T>A p.T186= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs1044799148, COSV99542719; called by muse, mutect2, varscan2
- PXDNL | c.3564C>T p.Y1188= | Silent (SNP) | VAF 34/51 reads (67%) | catalogued as rs376124066; called by muse, mutect2, varscan2
- SELP | c.1671G>A p.S557= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs762351992, COSV99738665, COSV99739987; called by muse, mutect2, varscan2
- TDRP | c.483C>T p.R161= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as rs375957326; called by muse, mutect2, varscan2
- THBS4 | c.429C>G p.L143= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100644272; called by muse, mutect2, varscan2
- TJP1 | c.5094G>A p.V1698= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs575536449, COSV62040356; called by muse, mutect2, varscan2
- TRIM46 | c.1749C>T p.G583= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as rs1241837433, COSV58112122; called by muse, mutect2, varscan2
